Surgical pathology report (de-identified scan), TCGA case TCGA-55-6968, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6968-01A (Primary Tumor).

DIAGNOSIS

DIAGNOSIS:

Lymph node, level 9, biopsy:

Anthracosis.

Negative for malignancy (two small lymph nodes).

Lymph nodes, level 7, excisional biopsy:

Anthracosis and reactive change, two lymph nodes.

Both are negative for malignancy.

Lung, right lower lobe, wedge resection:

Adenocarcinoma, poorly differentiated, with extensive necrosis.

Stapled surgical margin is free of malignancy.

Malignancy extends to within 0.1 mm of free pleural surface. Malignancy is 1.6 cm in greatest dimension.

Definite lymphovascular space invasion is not identified.

COMMENTS:

The malignancy is poorly differentiated, present in sheets in some areas. Focally, however, definite gland formation is present. The small cell component is not identified. The frozen section diagnosis is confirmed.

Staging sheet # 22

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

with right lung masses, rule out malignancy

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Level 9 lymph node

B. Level 7 lymph node

C. Right lower lobe lung nodule

SPECIMEN DATA

GROSS DESCRIPTION:

is a 0.5 cm soft yellow slightly lobular fragment. It is submitted whole in one cassette.

is a 1.1 x 0.6 x 0.2 cm rubbery brown lymph node. It is bisected and entirely submitted in one cassette.

and RLL nodule is a 6.3 gram wedge of lung tissue, 4.5 x 1.5 x 0.7 cm. The specimen has been partially sampled for frozen section. The margin is inked stapled. The pleura is gray and remarkable for an area of firm yellow discoloration and nodularity.

The staple is removed, the margin is inked and shaved. Further sectioning reveals a yellow chalky firm nodule, 1.6 x 1.5 x 1.4 cm. The nodule is 0.2 cm from the shave staple margin and less than 0.1 cm from the inked pleura. The uninvolved tissue is brown and spongy.

Representative sections are submitted as follows: 1--frozen section residue; 2 and 3--shave staple margin; 4 to 6--perpendicular sections through lesion; 7--uninvolved tissue. Cassette A research tissue labeled [REDACTED]

INTRA-OPERATIVE CONSULTATION:

Source: NCI Genomic Data Commons file e4eaf6b8-a2df-4646-92f7-0c7a6bc1bc1b (TCGA-55-6968.87F5CBE6-CCE1-4A8C-8189-C6FEABD3B4BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).